Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7688, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7688-01A (Primary Tumor).

Pathology Report for Subject [REDACTED]

Discussion: The calculated MIB-1 labeling index ranges up to 14.7%, consistent with a high grade glial neoplasm.

Microscopic Description: Sections demonstrate a markedly hypercellular glial neoplasm that diffusely infiltrates both gray and white matter. The majority of the tumor cells have round nuclei and well-formed perinuclear halos. Others cells have small eosinophilic caps with cytoplasm or microgemistocytic phenotype. The atypia is generally mild but many scattered moderately, or even markedly, atypical nuclei are seen. Mitotic activity is generally low, but in some areas up to 8 mitoses are seen in 10 high power fields. The tumor demonstrates both subpial condensation and perineuronal satellitosis. Neither microvascular proliferation nor necrosis are seen. Overall, the focally high proliferative activity suggests early anaplastic transformation in the background of a low grade oligodendroglioma.

Diagnosis: Anaplastic Oligodendroglioma (WHO grade III).
MIB-labeling index = 13.7%

Source: NCI Genomic Data Commons file 7f054127-e75b-4f52-8c0c-407cddd2254a (TCGA-HT-7688.35D09648-037F-4E5E-B70B-4F17CC8F2FB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).